Somatic mutation profile of tumor specimen TCGA-DA-A1IA-06A (aliquot TCGA-DA-A1IA-06A-11D-A196-08) from TCGA case TCGA-DA-A1IA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.2 years (13,599 days).
Specimen TCGA-DA-A1IA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f847f1aa-80cb-4bf4-a322-cbc354c6383e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1IA-10A (Blood Derived Normal), aliquot TCGA-DA-A1IA-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e30b2580-14e5-4e03-8d11-1e74f63726e5

The open-access MAF lists 438 somatic variants for this specimen: 271 protein-altering or splice-affecting, 157 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 157, Nonsense Mutation 21, Splice Site 7, Intron 6, Splice Region 5, Frame Shift Del 4, RNA 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- ABCD2 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58051171; called by muse, mutect2, varscan2
- AC004922.1 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as rs769870868, COSV53163071; called by muse, mutect2, varscan2
- ACAA1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV57172890; called by muse, mutect2, varscan2
- ACRBP | c.906T>G p.Y302* | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV57523545; called by muse, varscan2
- ACSBG2 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53123913; called by muse, mutect2, varscan2
- ADCY10 | c.4765G>A p.V1589I | Missense Mutation (SNP) | VAF 200/275 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs752087858, COSV63239848; called by muse, mutect2, varscan2
- ADGRD1 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1453980267, COSV55442496; called by muse, mutect2, varscan2
- ADGRE3 | c.1694G>A p.W565* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV53729726, COSV99506723; called by muse, mutect2, varscan2
- AGTPBP1 | c.1981G>A p.E661K (on ENST00000357081 / NM_001330701.2; = p.E621K on NM_015239.2) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100429381, COSV61269417, COSV61270454; called by muse, varscan2
- AKT1S1 | c.458-1G>A p.X153_splice (on ENST00000344175 / NM_001098633.4; = p.X173_splice on NM_032375.5) | Splice Site (SNP) | VAF 34/117 reads (29%) | catalogued as COSV59275365; called by muse, mutect2, varscan2
- AMZ1 | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 40/75 reads (53%) | catalogued as COSV56686009; called by muse, mutect2, varscan2
- ANKRD11 | c.5762C>T p.A1921V | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV56358987; called by muse, mutect2, varscan2
- ANOS1 | c.1842C>T p.S614= | Splice Region (SNP) | VAF 14/51 reads (27%) | catalogued as rs750983454, COSV52923501; called by muse, mutect2, varscan2
- ANOS1 | c.1841C>A p.S614Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99391367; called by muse, mutect2, varscan2
- ANXA7 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65823281; called by muse, mutect2, varscan2
- APLNR | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV57242022; called by muse, mutect2, varscan2
- ARHGEF11 | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 201/241 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100168919; called by muse, mutect2, varscan2
- ARHGEF11 | c.3868C>T p.P1290S | Missense Mutation (SNP) | VAF 198/239 reads (83%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100168920; called by muse, mutect2, varscan2
- ARHGEF2 | c.1825C>G p.R609G (on ENST00000361247 / NM_001162383.2; = p.R581G on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV58109091; called by muse, mutect2, varscan2
- ARMC4 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs532755252, COSV59461058; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ARRB2 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV52616987; called by muse, mutect2, varscan2
- ASPM | c.8756G>A p.R2919K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.283); catalogued as COSV54128066; called by muse, mutect2, varscan2
- ASS1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.801); catalogued as COSV61688975; called by muse, mutect2, varscan2
- ATP1A3 | c.2047G>A p.E683K (on ENST00000545399 / NM_001256214.2; = p.E670K on NM_152296.5) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs782439924, COSV57486709; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV52268921; called by muse, mutect2, varscan2
- ATP7A | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1557231632, COSV58444779; called by muse, mutect2, varscan2
- ATP8B4 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV52713142, COSV52715223; called by muse, mutect2, varscan2
- BAHCC1 | c.3466G>T p.E1156* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV57025161; called by muse, mutect2, varscan2
- BCAT1 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV53909962, COSV53910679; called by muse, mutect2, varscan2
- BIRC6 | c.14046T>G p.N4682K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70197778; called by muse, mutect2, varscan2
- BRS3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1569350463, COSV65710857; called by muse, mutect2, varscan2
- BRWD3 | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV64746580; called by muse, mutect2, varscan2
- BTNL8 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51458004; called by muse, mutect2, varscan2
- C14orf119 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.15); catalogued as COSV52975070; called by muse, mutect2, varscan2
- C2CD6 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV53793447; called by muse, mutect2, varscan2
- CALCOCO1 | c.2044T>G p.F682V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV50412922; called by muse, mutect2, varscan2
- CALML5 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV66702471; called by muse, mutect2, varscan2
- CASZ1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.17); catalogued as COSV59733541; called by muse, mutect2, varscan2
- CBLL1 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.55); catalogued as rs150861689, COSV56028599; called by muse, mutect2, varscan2
- CCDC110 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56870320; called by muse, mutect2, varscan2
- CDCA4 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs767578224, COSV60315241; called by muse, mutect2, varscan2
- CDH23 | c.9989A>C p.E3330A | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56456752; called by muse, mutect2, varscan2
- CDH7 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775706781, COSV59884116; called by muse, varscan2
- CDK13 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs922943045, COSV51698413; called by muse, mutect2, varscan2
- CEACAM1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1450885047, COSV99362591; called by muse, mutect2, varscan2
- CEACAM1 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV99362595; called by muse, mutect2, varscan2
- CELSR1 | c.6323C>T p.S2108F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs760321256, COSV53083800; called by muse, mutect2, varscan2
- CEMIP2 | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as COSV65486554; called by muse, mutect2, varscan2
- CHD1L | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV63613494; called by muse, mutect2, varscan2
- CHD7 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM060224, COSV71108931; called by muse, mutect2, varscan2
- CHMP6 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs769881954, COSV57327358; called by muse, mutect2, varscan2
- CIZ1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV52970927; called by muse, mutect2, varscan2
- CLSTN2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173990872, COSV71719958; called by muse, mutect2, varscan2
- CNGB1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV51899717; called by muse, mutect2, varscan2
- CNOT6 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 92/121 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56160871; called by muse, mutect2, varscan2
- CNST | c.617-1G>A p.X206_splice | Splice Site (SNP) | VAF 31/128 reads (24%) | catalogued as COSV63620195; called by muse, mutect2, varscan2
- CNTN2 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1314357549, COSV59349422; called by muse, mutect2, varscan2
- COL4A5 | c.2891G>A p.G964E | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60359416; called by muse, mutect2, varscan2
- CPD | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1357431098, COSV56712042; called by muse, mutect2, varscan2
- CRYBG1 | c.2923A>T p.I975F | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV64811654; called by muse, mutect2, varscan2
- CUBN | c.5969T>A p.F1990Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); catalogued as COSV64712959; called by muse, mutect2, varscan2
- CXXC1 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99497147; called by muse, mutect2, varscan2
- CYLC1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100255080, COSV61411294; called by muse, mutect2, varscan2
- CYP2B6 | c.367del p.V123Cfs*7 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV57843799; called by mutect2, pindel, varscan2
- DDX39A | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV54391110; called by muse, mutect2, varscan2
- DHX29 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV99287679; called by muse, mutect2, varscan2
- DHX8 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV52252254; called by muse, mutect2, varscan2
- DLC1 | c.2818G>A p.V940I (on ENST00000276297 / NM_001348081.2; = p.V503I on NM_006094.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV52299179; called by muse, mutect2, varscan2
- DNAH11 | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100180623; called by muse, mutect2, varscan2
- DNAH11 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60946993; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by muse, mutect2, varscan2
- DNALI1 | c.643-1G>A p.X215_splice (on ENST00000296218; = p.X193_splice on NM_003462.5) | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV56169493; called by muse, mutect2, varscan2
- DOCK11 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434014204, COSV52236787; called by muse, mutect2, varscan2
- DOCK7 | c.1038A>T p.L346= | Splice Region (SNP) | VAF 47/164 reads (29%) | catalogued as rs772265911, COSV52001868; called by muse, mutect2, varscan2
- DOK3 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768009784, COSV57251720; called by muse, mutect2, varscan2
- DPPA5 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV64875453; called by muse, mutect2, varscan2
- DSCAM | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 76/118 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV68024656; called by muse, mutect2, varscan2
- DUOX2 | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66531447, COSV66532801; called by muse, mutect2, varscan2
- DYRK4 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs141423818, COSV99158641; called by muse, mutect2, varscan2
- DZIP1 | c.355A>G p.K119E | Missense Mutation (SNP) | VAF 60/63 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61265090; called by muse, mutect2, varscan2
- E4F1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs770711229, COSV57038529; called by muse, mutect2, varscan2
- ECPAS | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV52195095; called by muse, mutect2, varscan2
- EPB41L2 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV61354412; called by muse, mutect2, varscan2
- EXOSC5 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs183362480, COSV99524744; called by muse, mutect2, varscan2
- FAM214B | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59715649; called by muse, mutect2, varscan2
- FAM50B | c.340A>T p.K114* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100976606; called by muse, mutect2, varscan2
- FBN2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506081; called by muse, mutect2, varscan2
- FBRS | c.597C>T p.F199= (on ENST00000287468; = p.F719= on NM_001105079.3) | Splice Region (SNP) | VAF 17/94 reads (18%) | catalogued as COSV54915647; called by muse, mutect2, varscan2
- FBXL6 | c.1226-1G>A p.X409_splice | Splice Site (SNP) | VAF 30/52 reads (58%) | catalogued as COSV57351522; called by muse, mutect2, varscan2
- FBXO11 | c.506C>T p.S169F (on ENST00000403359 / NM_001190274.2; = p.S85F on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57018180; called by muse, mutect2, varscan2
- FBXO38 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57026947; called by muse, mutect2, varscan2
- FBXO47 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as COSV65241579; called by muse, mutect2, varscan2
- FEM1C | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV57231266; called by muse, mutect2, varscan2
- FHL5 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs760536455, COSV58736837; called by muse, mutect2, varscan2
- FJX1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100502726, COSV58552759; called by muse, mutect2, varscan2
- FLNA | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV61041013; called by muse, mutect2, varscan2
- FLT4 | c.3268G>A p.V1090M | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV56104914; called by muse, mutect2, varscan2
- FRMPD4 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV66211748; called by muse, mutect2, varscan2
- GDF5 | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV65500604; called by muse, mutect2, varscan2
- GIGYF2 | c.1631A>C p.E544A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65248255; called by muse, mutect2, varscan2
- GLRA1 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV51009451; called by muse, mutect2, varscan2
- GRIP2 | c.3001G>A p.V1001M (on ENST00000619221; = p.V904M on NM_001080423.4) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs768784360, COSV56120846; called by muse, mutect2, varscan2
- HCN2 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99242279; called by muse, mutect2, varscan2
- HDAC9 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67770898; called by muse, mutect2, varscan2
- HECTD3 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV64669784; called by muse, mutect2, varscan2
- HECW2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as rs375997058; called by muse, mutect2, varscan2
- HMCN1 | c.14609G>A p.G4870D | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54891117; called by muse, mutect2, varscan2
- INPP5J | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV58512501; called by muse, mutect2, varscan2
- INTS2 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99248722; called by muse, mutect2, varscan2
- INTS2 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV99248017, COSV99248105, COSV99248724; called by muse, mutect2, varscan2
- IQSEC2 | c.911C>T p.A304V (on ENST00000642864 / NM_001111125.3; = p.A99V on NM_015075.2) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64724745; called by muse, mutect2, varscan2
- IREB2 | c.910del p.V304Lfs*19 | Frame Shift Del (DEL) | VAF 52/118 reads (44%) | catalogued as COSV51921837; called by mutect2, pindel, varscan2
- KAT6B | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54745111, COSV54754725; called by muse, mutect2, varscan2
- KCNH8 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs764123756, COSV60460701; called by muse, mutect2, varscan2
- KCNV1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.134); catalogued as COSV52084940; called by muse, mutect2, varscan2
- KDM8 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.055); catalogued as COSV53729160; called by muse, mutect2, varscan2
- KIAA1109 | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99174710; called by muse, mutect2, varscan2
- KIAA1109 | c.3917C>T p.P1306L | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52669499; called by muse, mutect2, varscan2
- KIF14 | c.1977A>G p.T659= | Splice Region (SNP) | VAF 25/60 reads (42%) | catalogued as rs745318634, COSV66261140; called by muse, mutect2, varscan2
- KIF4B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1233434641, COSV70528516; called by muse, mutect2, varscan2
- KIF5C | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV101276223, COSV68480694; called by muse, mutect2, varscan2
- KRT1 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs267603525, COSV52864997, COSV52866014; called by muse, mutect2
- KRT71 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV57289703; called by muse, mutect2, varscan2
- LIME1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.37); catalogued as COSV56649259; called by muse, mutect2, varscan2
- LIPI | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753905, COSV60707749; called by muse, mutect2, varscan2
- LRRIQ3 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV63042745; called by muse, mutect2, varscan2
- LRRN2 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100912954; called by muse, mutect2, varscan2
- LTBP3 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54211827; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 197/482 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417622359, COSV65442727; called by muse, mutect2, varscan2
- LYPLAL1 | c.312G>T p.L104F | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV65106466; called by muse, mutect2, varscan2
- MCF2L2 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV100193820; called by muse, mutect2, varscan2
- MCF2L2 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100193824; called by muse, mutect2, varscan2
- MED26 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs754302632, COSV54659700; called by muse, mutect2, varscan2
- MPO | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV51858100; called by muse, mutect2, varscan2
- MRGPRD | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs898779097, COSV58422855, COSV58423503; called by muse, mutect2, varscan2
- MUC17 | c.7945G>A p.E2649K | Missense Mutation (SNP) | VAF 150/160 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1170444838, COSV60285451; called by muse, mutect2, varscan2
- MYBPC2 | c.2159G>A p.G720E | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1156328856, COSV63094529; called by muse, mutect2, varscan2
- NAA25 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs759992055, COSV99927989; called by muse, mutect2, varscan2
- NAF1 | c.203A>C p.Q68P | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV56803966; called by muse, varscan2
- NEB | c.19262C>T p.P6421L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99427471; called by muse, mutect2, varscan2
- NOL9 | c.745A>G p.S249G | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV66625723; called by muse, mutect2, varscan2
- NOX3 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 26/27 reads (96%) | catalogued as COSV50150148; called by muse, mutect2, varscan2
- NPAP1 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.935); catalogued as COSV61505968; called by muse, mutect2, varscan2
- NXPH2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55641550; called by muse, mutect2, varscan2
- OIT3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV61825739; called by muse, mutect2, varscan2
- OR14A16 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV62926428; called by muse, mutect2, varscan2
- OR4K13 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100237924, COSV59859393; called by muse, mutect2, varscan2
- OR4K5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV60003041; called by muse, mutect2, varscan2
- OR51B5 | c.425T>A p.I142N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56175592; called by muse, mutect2, varscan2
- OR6Y1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs762447565, COSV56929008; called by muse, mutect2, varscan2
- OR7G1 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 54/98 reads (55%) | catalogued as rs753956107, COSV53317457; called by muse, mutect2, varscan2
- OR9G1 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs761706823, COSV100380549; called by muse, mutect2, varscan2
- OTOR | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 156/256 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV55721907; called by muse, mutect2, varscan2
- OVGP1 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63858123; called by muse, mutect2, varscan2
- PACS1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV57697267; called by muse, mutect2, varscan2
- PCDHA12 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.078); catalogued as rs17844352, COSV56491917, COSV56505360; called by muse, mutect2, varscan2
- PCDHA3 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV63540408; called by muse, mutect2, varscan2
- PCDHB6 | c.892del p.E298Kfs*4 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as COSV50690112, COSV50716913; called by mutect2, pindel, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, varscan2
- PCDHGB1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 42/71 reads (59%) | catalogued as COSV99532582, COSV99546161; called by muse, mutect2, varscan2
- PCMTD1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.035); catalogued as COSV62121074; called by muse, mutect2
- PDE11A | c.1481A>T p.D494V | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53691342; called by muse, mutect2, varscan2
- PDE6B | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1246209750, COSV55325383; called by muse, mutect2, varscan2
- PEG3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); catalogued as rs754206051, COSV55630260, COSV99690320; called by muse, mutect2, varscan2
- PERP | c.574T>G p.S192A | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV69827443; called by muse, mutect2, varscan2
- PEX11B | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100995033; called by muse, mutect2, varscan2
- PEX11B | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as COSV100995013, COSV100995032; called by muse, mutect2, varscan2
- PGGT1B | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56973658; called by muse, mutect2, varscan2
- PGR | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs763952401, COSV54799397; called by muse, mutect2, varscan2
- PIKFYVE | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149384342; called by muse, mutect2, varscan2
- PLEKHG3 | c.3260G>A p.R1087Q (on ENST00000394691; = p.R1143Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752309030, COSV99907061; called by muse, mutect2, varscan2
- PLEKHG4 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58572182; called by muse, mutect2, varscan2
- PLEKHJ1 | c.400T>C p.F134L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV55554221; called by muse, mutect2
- PLXDC2 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs368244668, COSV65900642; called by muse, mutect2, varscan2
- PMEL | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV62428393; called by muse, mutect2, varscan2
- PNPLA7 | c.1782G>A p.W594* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV52997255; called by muse, mutect2, varscan2
- POGZ | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55034354; called by muse, mutect2, varscan2
- PPP1R9A | c.1956G>A p.M652I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56888533; called by muse, mutect2, varscan2
- PPTC7 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 58/92 reads (63%) | catalogued as COSV62825985; called by muse, mutect2, varscan2
- PRG2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV61293404; called by muse, mutect2, varscan2
- PROC | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs1443672925, COSV52165373; called by muse, mutect2, varscan2
- PSG6 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.257); catalogued as COSV51831920; called by muse, mutect2, varscan2
- PZP | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs767886293, COSV54357918; called by muse, mutect2, varscan2
- RASAL2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62712250; called by muse, mutect2, varscan2
- REN | c.699-1G>A p.X233_splice | Splice Site (SNP) | VAF 73/130 reads (56%) | catalogued as rs767635174, COSV65817596; called by muse, mutect2, varscan2
- RHBDF2 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 68/108 reads (63%) | catalogued as COSV51684190; called by muse, mutect2, varscan2
- RHEB | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100062359; called by muse, mutect2, varscan2
- RHEB | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100062362; called by muse, mutect2, varscan2
- RNF213 | c.15431C>T p.P5144L | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100301406; called by muse, mutect2, varscan2
- RPRD2 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.027); catalogued as COSV64819392; called by muse, mutect2, varscan2
- RPS6KA2 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773211344, COSV55818892; called by muse, mutect2, varscan2
- RS1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66106122; called by muse, mutect2, varscan2
- RSF1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 108/185 reads (58%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV57838504; called by muse, mutect2, varscan2
- SACS | c.6346C>T p.P2116S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66538308; called by muse, mutect2, varscan2
- SAMD4B | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV58751009; called by muse, varscan2
- SF3A3 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65955724; called by muse, mutect2, varscan2
- SHROOM3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533735013, COSV99933623; called by muse, mutect2, varscan2
- SLC22A7 | c.515G>T p.R172L (on ENST00000372585 / NM_153320.2; = p.R170L on NM_006672.3) | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV65353981; called by muse, mutect2, varscan2
- SLC25A53 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100655811; called by muse, mutect2
- SLC30A9 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs778912116, COSV52555222; called by muse, mutect2, varscan2
- SLC36A3 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58856471; called by muse, mutect2, varscan2
- SLC39A12 | c.98A>T p.D33V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV66197115; called by muse, varscan2
- SLC44A5 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs200618502, COSV63762151; called by muse, mutect2, varscan2
- SLC45A2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs778521952, COSV56871008; called by muse, mutect2, varscan2
- SMG6 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs1310229263, COSV99558686; called by muse, mutect2, varscan2
- SMG6 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as COSV99558689; called by muse, mutect2, varscan2
- SNRK | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs889935483, COSV56066227; called by muse, mutect2, varscan2
- SNX7 | c.1091A>C p.E364A | Missense Mutation (SNP) | VAF 135/234 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV60267661; called by muse, mutect2, varscan2
- SP7 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs1185140332, COSV58190753; called by muse, mutect2, varscan2
- SPECC1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765197010, COSV54960895; called by muse, mutect2, varscan2
- SPRR4 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 38/251 reads (15%) | catalogued as COSV60142709; called by muse, mutect2, varscan2
- SPTBN4 | c.5587C>T p.P1863S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV58946974; called by muse, mutect2, varscan2
- SSH1 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV58455763; called by muse, mutect2, varscan2
- SST | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 126/310 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.358); catalogued as COSV55030581; called by muse, mutect2, varscan2
- ST14 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53832662; called by muse, mutect2, varscan2
- STAM | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs371026356, COSV66325159; called by muse, mutect2, varscan2
- STX3 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55696870; called by muse, mutect2, varscan2
- TACR2 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.25); catalogued as COSV100067888; called by muse, mutect2
- TACR2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.316); catalogued as COSV100067891; called by muse, mutect2
- TAF13 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 141/398 reads (35%) | catalogued as rs754893278, CM142618, COSV58039693; called by muse, mutect2, varscan2
- TBC1D7 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58243720; called by muse, mutect2, varscan2
- TBC1D8B | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99345016; called by muse, mutect2, varscan2
- TBC1D8B | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345019; called by muse, mutect2, varscan2
- TCAIM | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61240584; called by muse, mutect2, varscan2
- TCL1B | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as rs763544217, COSV61551879, COSV61552413; called by muse, mutect2, varscan2
- TEX33 | c.343C>T p.P115S (on ENST00000381821 / NM_001163857.2; = p.P30S on NM_178552.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV67821654; called by muse, mutect2, varscan2
- TFR2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV56153745; called by muse, mutect2, varscan2
- THOC2 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV55543997; called by muse, mutect2, varscan2
- THSD7B | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as COSV55673230; called by muse, mutect2, varscan2
- THSD7B | c.2751G>C p.E917D | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV55673250; called by muse, mutect2, varscan2
- TLE2 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53579406; called by muse, mutect2, varscan2
- TLK1 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 68/107 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV62629795; called by muse, mutect2, varscan2
- TMC3 | c.312G>A p.E104= | Splice Region (SNP) | VAF 74/125 reads (59%) | catalogued as rs560112819, COSV63922706; called by muse, mutect2, varscan2
- TMCO1 | c.701C>T p.P234L (on ENST00000612311 / NM_001256164.1; = p.P183L on NM_019026.6) | Missense Mutation (SNP) | VAF 52/449 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV63317962; called by muse, mutect2, varscan2
- TMEM202 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV58982277; called by muse, mutect2, varscan2
- TNR | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.403); catalogued as COSV54879253; called by muse, mutect2, varscan2
- TOPORS | c.2942C>T p.T981I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV62116638; called by muse, mutect2, varscan2
- TPM1 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as CM010475, COSV51260425; called by muse, mutect2, varscan2
- TRIM23 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51550639; called by muse, mutect2, varscan2
- TRIM55 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52544544, COSV52545341; called by muse, mutect2, varscan2
- TRPV6 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1489493030, COSV63891147; called by muse, mutect2, varscan2
- TRPV6 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs1239027358, COSV63891253; called by muse, mutect2, varscan2
- TTN | c.100528G>A p.D33510N (on ENST00000591111; = p.D26086N on NM_003319.4) | Missense Mutation (SNP) | VAF 55/203 reads (27%) | PolyPhen benign (0.274); catalogued as COSV59983299; called by muse, mutect2, varscan2
- TTN | c.54460G>A p.E18154K (on ENST00000591111; = p.E10730K on NM_003319.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | PolyPhen probably damaging (0.994); catalogued as COSV59983331; called by muse, mutect2, varscan2
- TTN | c.11983G>A p.E3995K (on ENST00000591111; = p.E3949K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs867098026, COSV59961437; called by muse, mutect2, varscan2
- TUBB6 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99302146; called by muse, mutect2, varscan2
- TUBB8 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.886); catalogued as rs782029140, COSV59115276; called by muse, mutect2, varscan2
- TXLNA | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65314126; called by muse, mutect2, varscan2
- UBN2 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 68/163 reads (42%) | catalogued as COSV56029445; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV51954456; called by muse, mutect2
- UHRF1BP1 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs771598912, COSV51962263; called by muse, mutect2
- VN1R4 | c.781A>G p.N261D | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs1350462121, COSV60804846, COSV60805208; called by muse, mutect2, varscan2
- VWA5A | c.2281+1G>T p.X761_splice | Splice Site (SNP) | VAF 16/55 reads (29%) | catalogued as COSV64412448; called by muse, mutect2, varscan2
- WDR90 | c.5194C>T p.L1732F | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1327595440, COSV53468359; called by muse, mutect2, varscan2
- WDR93 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51531539; called by muse, mutect2
- XIAP | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.952); catalogued as COSV100848976; called by muse, mutect2, varscan2
- XIAP | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100848977; called by muse, mutect2, varscan2
- XIRP2 | c.6755C>T p.P2252L (on ENST00000628543; = p.P2427L on NM_152381.6) | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV54692959, COSV54727408; called by muse, mutect2, varscan2
- YPEL2 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 55/104 reads (53%) | catalogued as COSV57071799; called by muse, mutect2, varscan2
- ZDHHC1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52083728; called by muse, varscan2
- ZNF213 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV67727652; called by muse, mutect2, varscan2
- ZNF236 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV53485735; called by muse, mutect2, varscan2
- ZNF257 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV101448155, COSV71306235; called by muse, mutect2, varscan2
- ZNF436 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.687); catalogued as rs762085274, COSV58358354; called by muse, mutect2, varscan2
- ZNF462 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.157); catalogued as COSV52932206; called by muse, mutect2, varscan2
- ZNF577 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as COSV100031082, COSV56815007; called by muse, mutect2, varscan2
- ZNFX1 | c.3731G>A p.S1244N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.856); catalogued as COSV65596083; called by muse, mutect2, varscan2
- CYFIP1 | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAT4 | c.579_591del p.Q193Hfs*20 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- ABCB8 | c.1506C>T p.I502= (on ENST00000297504 / NM_001282291.2; = p.I485= on NM_007188.5) | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs777923801, COSV52503632; called by mutect2, varscan2
- ACTG1 | c.795C>T p.S265= | Silent (SNP) | VAF 78/149 reads (52%) | catalogued as rs146493032; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2817C>T p.F939= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV54443151; called by muse, mutect2, varscan2
- AKAP9 | c.2661A>G p.L887= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV62343271; called by muse, mutect2, varscan2
- ALDH2 | c.1395G>A p.A465= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs778990792, COSV55666304; called by muse, mutect2, varscan2
- AMPD3 | c.1149C>T p.F383= (on ENST00000396553 / NM_001025389.2; = p.F392= on NM_000480.3) | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs771556714, COSV67330547; called by muse, mutect2, varscan2
- ANKRD45 | c.570G>A p.G190= | Silent (SNP) | VAF 81/150 reads (54%) | catalogued as rs1336295515, COSV60960021; called by muse, mutect2, varscan2
- ANP32D | c.69C>T p.F23= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs1476485728, COSV56980357; called by muse, varscan2
- APOBEC1 | c.54C>T p.I18= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs893745121, COSV57548600; called by muse, mutect2, varscan2
- ARAF | c.1116C>T p.F372= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV51692169; called by muse, mutect2, varscan2
- ASB16 | c.27C>T p.T9= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV53234528; called by muse, mutect2, varscan2
- B3GALT5 | c.822C>T p.S274= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs372655965; called by muse, mutect2, varscan2
- BAG5 | c.1314C>T p.L438= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs764055806, COSV54570744; called by muse, mutect2, varscan2
- BTN2A2 | c.1194C>T p.V398= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV61857035; called by muse, mutect2, varscan2
- C7 | c.315G>A p.G105= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV57473062; called by muse, mutect2, varscan2
- CA1 | c.462C>T p.A154= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV56278150; called by muse, mutect2, varscan2
- CABIN1 | c.5676C>T p.I1892= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV54080375; called by muse, mutect2, varscan2
- CACNA2D3 | c.1863C>T p.S621= | Silent (SNP) | VAF 126/305 reads (41%) | catalogued as COSV55528744; called by muse, mutect2, varscan2
- CACNG3 | c.351C>T p.F117= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs774241889, COSV50064207; called by muse, mutect2, varscan2
- CAMSAP1 | c.1116C>T p.F372= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs546949363, COSV56721170; called by muse, mutect2, varscan2
- CBFA2T2 | c.123C>T p.S41= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV60073609; called by muse, mutect2, varscan2
- CCDC89 | c.133C>T p.L45= | Silent (SNP) | VAF 23/25 reads (92%) | catalogued as COSV100320896, COSV57033819; called by muse, mutect2, varscan2
- CD180 | c.588G>A p.L196= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV56517528; called by muse, mutect2, varscan2
- CEACAM18 | c.447G>A p.V149= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV67282596; called by muse, mutect2, varscan2
- CFAP70 | c.1527G>A p.K509= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV60282378; called by muse, mutect2, varscan2
- CHL1 | c.1887G>A p.R629= (on ENST00000397491 / NM_001253387.1; = p.R645= on NM_006614.4) | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV56590611; called by muse, mutect2, varscan2
- CHMP6 | c.525C>T p.S175= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as rs773215747, COSV100289543; called by muse, mutect2, varscan2
- CHRNB2 | c.240T>C p.N80= | Silent (SNP) | VAF 199/260 reads (77%) | catalogued as COSV63808001; called by muse, mutect2, varscan2
- CIC | c.1356C>T p.V452= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV50557844; called by muse, mutect2, varscan2
- CLDN23 | c.277C>T p.L93= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs772534069, COSV67731492; called by muse, mutect2, varscan2
- CMA1 | c.300A>G p.P100= | Silent (SNP) | VAF 57/93 reads (61%) | catalogued as COSV51625242; called by muse, mutect2, varscan2
- COX7A2L | c.222C>T p.P74= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs373859176; called by muse, mutect2, varscan2
- CSPG5 | c.1590G>A p.L530= (on ENST00000383738 / NM_001206943.2; = p.L503= on NM_006574.4) | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as COSV53130675; called by muse, mutect2, varscan2
- CXXC1 | c.1080C>T p.H360= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs1213153515, COSV99497148; called by muse, mutect2, varscan2
- CYFIP1 | c.2511G>A p.G837= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- DCAF15 | c.993C>T p.A331= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV54328940; called by muse, mutect2, varscan2
- DCBLD2 | c.282C>T p.P94= | Silent (SNP) | VAF 87/221 reads (39%) | catalogued as COSV58788772; called by muse, mutect2, varscan2
- DDHD2 | c.783G>A p.Q261= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1563303384, COSV68157609; called by muse, mutect2, varscan2
- DHX29 | c.363C>T p.A121= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV99287678; called by muse, mutect2, varscan2
- DHX37 | c.1071C>T p.I357= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV58133474; called by muse, mutect2, varscan2
- DLC1 | c.2817G>A p.S939= (on ENST00000276297 / NM_001348081.2; = p.S502= on NM_006094.5) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99365286; called by muse, mutect2, varscan2
- DMRTA1 | c.1164G>A p.Q388= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100364889; called by muse, mutect2, varscan2
- DNAH10 | c.5331C>T p.H1777= (on ENST00000409039; = p.H1716= on NM_207437.3) | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV68991395; called by muse, mutect2, varscan2
- DUSP7 | c.855C>T p.F285= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as rs1444614926, COSV56588781; called by muse, mutect2, varscan2
- EHBP1L1 | c.363C>T p.A121= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV58572339; called by muse, mutect2, varscan2
- EHBP1L1 | c.2598C>T p.T866= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs1212863068, COSV58572346; called by muse, mutect2, varscan2
- ELOA | c.1002C>T p.S334= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1266148437, COSV101403823; called by muse, mutect2, varscan2
- ELOA | c.1003C>T p.L335= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101403824; called by muse, mutect2, varscan2
- EPHA6 | c.1326T>A p.I442= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV67567582; called by muse, mutect2, varscan2
- EPHB2 | c.2289G>A p.S763= (on ENST00000400191 / NM_001309193.2; = p.S764= on NM_004442.7) | Silent (SNP) | VAF 49/71 reads (69%) | catalogued as rs147014777; called by muse, mutect2, varscan2
- EXOSC10 | c.2397C>T p.L799= (on ENST00000376936 / NM_001001998.3; = p.L774= on NM_002685.4) | Silent (SNP) | VAF 160/604 reads (26%) | catalogued as COSV58664827; called by muse, varscan2
- FBXO27 | c.621A>G p.Q207= | Silent (SNP) | VAF 69/124 reads (56%) | catalogued as rs958233569, COSV53072157; called by muse, mutect2, varscan2
- FCSK | c.127C>T p.L43= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV55369324; called by muse, mutect2, varscan2
- FGF23 | c.324C>T p.F108= | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as rs201114020, COSV52975615; called by muse, mutect2, varscan2
- FLT4 | c.3267G>A p.K1089= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV99988775; called by muse, mutect2, varscan2
- FRMPD1 | c.648C>T p.I216= | Silent (SNP) | VAF 50/81 reads (62%) | catalogued as COSV66699983; called by muse, mutect2, varscan2
- GABRG3 | c.399C>T p.F133= | Silent (SNP) | VAF 50/78 reads (64%) | catalogued as COSV61514697; called by muse, mutect2, varscan2
- GLMN | c.663G>A p.L221= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV64860167; called by muse, mutect2, varscan2
- GPNMB | c.252T>C p.S84= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as COSV51697788; called by muse, mutect2, varscan2
- GPR142 | c.525C>T p.L175= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs762520062, COSV59518832; called by muse, mutect2, varscan2
- HMCN1 | c.13647C>T p.I4549= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV54891106; called by muse, mutect2, varscan2
- HSPBP1 | c.370C>T p.L124= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99729268; called by muse, mutect2, varscan2
- HSPBP1 | c.369C>T p.A123= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1471938417, COSV99729270; called by muse, mutect2, varscan2
- IL11RA | c.204C>T p.L68= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs1385837554, COSV58840422; called by muse, mutect2, varscan2
- INSRR | c.3561C>T p.T1187= | Silent (SNP) | VAF 237/306 reads (77%) | catalogued as COSV63872140; called by muse, mutect2, varscan2
- ITGA2B | c.3078G>A p.R1026= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV52232076; called by muse, mutect2, varscan2
- JAK2 | c.3130C>T p.L1044= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV67599912; called by muse, mutect2, varscan2
- KCNH6 | c.2562C>T p.P854= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as COSV59002453; called by muse, mutect2, varscan2
- KIF2B | c.1884T>C p.G628= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV52129223; called by muse, mutect2, varscan2
- KRT77 | c.1572C>T p.S524= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV59239272; called by muse, mutect2
- LIMD1 | c.699C>T p.S233= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV99837131; called by muse, mutect2, varscan2
- LIMD1 | c.700C>T p.L234= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs1179796811, COSV99837132, COSV99837220; called by muse, mutect2, varscan2
- LPIN1 | c.840G>A p.Q280= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV56764290; called by muse, mutect2, varscan2
- LRRN2 | c.1347C>T p.A449= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs780598649, COSV100912953; called by muse, mutect2, varscan2
- MAP1A | c.6276C>T p.S2092= | Silent (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- MCOLN1 | c.1042C>T p.L348= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV51174722; called by muse, mutect2, varscan2
- MDGA1 | c.111G>A p.V37= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs769996181, COSV51794392; called by muse, mutect2, varscan2
- MED14 | c.2925A>G p.R975= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs781055416, COSV61356522; called by muse, mutect2, varscan2
- MFSD10 | c.942C>T p.L314= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as COSV53268025; called by muse, mutect2, varscan2
- MICAL1 | c.1341C>T p.S447= | Silent (SNP) | VAF 43/52 reads (83%) | catalogued as COSV62192929; called by muse, mutect2, varscan2
- MRTO4 | c.177C>T p.A59= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV57673700; called by muse, mutect2, varscan2
- MSANTD1 | c.546C>T p.F182= | Silent (SNP) | VAF 120/137 reads (88%) | catalogued as rs765402226, COSV70873225; called by muse, mutect2, varscan2
- MUC16 | c.29643G>A p.E9881= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV67458505; called by muse, mutect2, varscan2
- MUC17 | c.13227C>T p.L4409= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV60285460; called by muse, mutect2, varscan2
- MYH13 | c.4344G>A p.K1448= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs1464654774, COSV52825053; called by muse, mutect2, varscan2
- MYO18A | c.2910C>T p.I970= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV62865062; called by muse, mutect2, varscan2
- MYO1F | c.1293C>T p.I431= | Silent (SNP) | VAF 119/187 reads (64%) | catalogued as COSV100597039; called by muse, mutect2, varscan2
- NAA25 | c.1848G>A p.R616= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV99927987; called by muse, mutect2, varscan2
- NEB | c.19263C>T p.P6421= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1170681985, COSV99427463; called by muse, mutect2, varscan2
- NEFL | c.219G>A p.L73= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1321286875, COSV55336698; called by muse, mutect2, varscan2
- NEUROD4 | c.987C>T p.F329= | Silent (SNP) | VAF 85/276 reads (31%) | catalogued as rs761841454, COSV54470584; called by muse, mutect2, varscan2
- NFE2 | c.1074G>A p.G358= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV56455595; called by muse, mutect2, varscan2
- NLRP13 | c.1548C>T p.L516= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs756221722, COSV61621116; called by muse, mutect2, varscan2
- NLRP2 | c.570G>A p.K190= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as COSV54753923; called by muse, mutect2, varscan2
- NUGGC | c.2304G>A p.A768= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs765700940, COSV100429754; called by muse, mutect2, varscan2
- NUMBL | c.411C>T p.V137= | Silent (SNP) | VAF 102/148 reads (69%) | catalogued as rs112715509; called by muse, mutect2, varscan2
- OR13C9 | c.444C>T p.S148= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV52241451; called by muse, mutect2, varscan2
- OR2G3 | c.339C>T p.I113= | Silent (SNP) | VAF 179/281 reads (64%) | catalogued as rs267598475, COSV60680836; called by muse, mutect2, varscan2
- OR4C11 | c.330C>T p.I110= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV56352816, COSV56354100; called by muse, mutect2, varscan2
- OR52H1 | c.531C>T p.P177= (on ENST00000322653; = p.P183= on NM_001005289.1) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV59504987; called by muse, varscan2
- OR5D13 | c.192C>T p.F64= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1372658586, COSV100686783, COSV62333353; called by muse, mutect2, varscan2
- OR6C2 | c.762C>T p.I254= | Silent (SNP) | VAF 53/84 reads (63%) | catalogued as rs761943433, COSV100498715, COSV59515823; called by muse, mutect2, varscan2
- PATJ | c.2967C>T p.I989= | Silent (SNP) | VAF 74/117 reads (63%) | catalogued as COSV57159783; called by muse, mutect2, varscan2
- PCDHGB1 | c.744C>T p.L248= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as rs964159189, COSV99546157; called by muse, mutect2, varscan2
- PCNT | c.9325C>T p.L3109= | Silent (SNP) | VAF 66/95 reads (69%) | catalogued as COSV64027027; called by muse, mutect2, varscan2
- PLCB3 | c.127C>T p.L43= | Silent (SNP) | VAF 38/179 reads (21%) | catalogued as rs1344449750, COSV54187445; called by muse, mutect2, varscan2
- PLEKHG3 | c.3261G>A p.R1087= (on ENST00000394691; = p.R1143= on NM_001308147.2) | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV99907058; called by muse, mutect2, varscan2
- POLG2 | c.1363C>T p.L455= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV101604445; called by muse, mutect2, varscan2
- PRAMEF15 | c.981C>T p.T327= | Silent (SNP) | VAF 109/383 reads (28%) | called by muse, mutect2, varscan2
- PRDM9 | c.1386C>T p.L462= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs369950735, COSV57012555; called by muse, mutect2, varscan2
- PTCHD3 | c.642C>T p.V214= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV71256644; called by muse, mutect2, varscan2
- RGL4 | c.249G>A p.R83= | Silent (SNP) | VAF 79/178 reads (44%) | catalogued as rs1569118162, COSV51943474; called by muse, mutect2, varscan2
- RIMS4 | c.363C>T p.I121= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs375033267; called by muse, mutect2, varscan2
- RNF213 | c.15432C>T p.P5144= | Silent (SNP) | VAF 56/138 reads (41%) | catalogued as COSV100301407; called by muse, mutect2, varscan2
- RPA4 | c.756G>A p.V252= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV61265355; called by muse, mutect2, varscan2
- RXFP2 | c.1368C>T p.I456= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV53633277; called by muse, mutect2
- SCTR | c.276C>T p.F92= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as COSV50027415, COSV99191561; called by muse, mutect2, varscan2
- SEC16A | c.1209C>T p.F403= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV51525361; called by muse, mutect2, varscan2
- SERPINA7 | c.345G>A p.L115= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as COSV59665449; called by muse, mutect2, varscan2
- SHROOM3 | c.1164G>A p.R388= | Silent (SNP) | VAF 35/37 reads (95%) | catalogued as COSV99935243; called by muse, mutect2, varscan2
- SLC25A53 | c.900C>T p.S300= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100656127; called by muse, mutect2, varscan2
- SLC38A10 | c.795C>T p.P265= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs1438194753, COSV55844524; called by muse, mutect2
- SLC5A7 | c.360A>G p.Q120= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV50890435; called by muse, mutect2, varscan2
- SLCO6A1 | c.1836T>G p.R612= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV65808392; called by muse, mutect2, varscan2
- SNX32 | c.516G>A p.K172= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV57449275; called by muse, mutect2, varscan2
- SPEG | c.5463C>T p.F1821= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100405537; called by muse, mutect2, varscan2
- SPEG | c.5464C>T p.L1822= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100405538, COSV56668716; called by muse, mutect2, varscan2
- ST6GAL1 | c.349C>T p.L117= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1353118047, COSV51468483; called by muse, mutect2, varscan2
- TAS2R7 | c.357C>T p.F119= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs867775726, COSV53688531; called by muse, mutect2, varscan2
- TBL3 | c.1446C>T p.I482= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV60341206; called by muse, mutect2, varscan2
- TEFM | c.123G>A p.K41= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV60091759; called by muse, mutect2, varscan2
- TIAM2 | c.2100C>T p.S700= | Silent (SNP) | VAF 68/76 reads (89%) | catalogued as COSV100020024; called by muse, mutect2, varscan2
- TIAM2 | c.2101C>T p.L701= | Silent (SNP) | VAF 67/75 reads (89%) | catalogued as COSV100020026; called by muse, mutect2, varscan2
- TLR9 | c.2242C>T p.L748= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV62346286; called by muse, mutect2, varscan2
- TMEM81 | c.249C>T p.T83= | Silent (SNP) | VAF 77/130 reads (59%) | catalogued as COSV52703961; called by muse, mutect2, varscan2
- TRRAP | c.4314G>A p.R1438= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV62842439; called by muse, mutect2, varscan2
- TTC24 | c.1542G>A p.G514= | Silent (SNP) | VAF 66/394 reads (17%) | catalogued as COSV63997443; called by muse, mutect2, varscan2
- TUBB2B | c.1224C>T p.F408= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99455619; called by muse, mutect2, varscan2
- TUBB6 | c.690C>T p.S230= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV99302149; called by muse, mutect2, varscan2
- TULP1 | c.1152C>T p.N384= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs371436525, COSV57693574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXLNB | c.1542G>A p.E514= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as rs1346880144, COSV64443658; called by muse, mutect2, varscan2
- UGGT1 | c.903G>A p.L301= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV52134274; called by muse, mutect2, varscan2
- ULK1 | c.2250C>T p.S750= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs374869166; called by muse, mutect2
- UNC45A | c.885C>T p.I295= | Silent (SNP) | VAF 157/477 reads (33%) | catalogued as rs1010007696, COSV67816135; called by muse, mutect2, varscan2
- USH2A | c.9183C>T p.L3061= | Silent (SNP) | VAF 57/92 reads (62%) | catalogued as COSV56353793; called by muse, mutect2, varscan2
- YPEL2 | c.30C>T p.F10= | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as COSV100445431; called by muse, mutect2, varscan2
- ZBTB7B | c.786C>T p.S262= (on ENST00000292176; = p.S296= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV52692099; called by muse, mutect2, varscan2
- ZDBF2 | c.5700C>T p.V1900= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV65624146; called by muse, mutect2, varscan2
- ZNF138 | c.501C>T p.F167= (on ENST00000307355 / NM_001367572.1; = p.F141= on NM_006524.4) | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs61732253, COSV56464620; called by muse, mutect2, varscan2
- ZNF189 | c.342C>T p.F114= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV52274934, COSV52277259; called by muse, mutect2, varscan2
- ZNF257 | c.1602G>A p.K534= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV71306674; called by mutect2, varscan2
- ZNF285 | c.1239C>T p.S413= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs566967165, COSV58408563, COSV58410133; called by muse, mutect2, varscan2
- ZNF395 | c.684C>T p.S228= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV60428198; called by muse, mutect2, varscan2
- ZNF441 | c.504C>T p.L168= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV63539502; called by muse, mutect2, varscan2
- ZNF516 | c.243C>T p.I81= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1359094941, COSV71586880; called by muse, mutect2
- ZNF517 | c.699C>T p.F233= | Silent (SNP) | VAF 7/8 reads (88%) | catalogued as COSV63464762; called by muse, mutect2, varscan2
- ZNF713 | c.762C>T p.F254= (on ENST00000633730 / NM_001366796.2; = p.F267= on NM_182633.3) | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV70056598; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504273 G>A | 5'Flank (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2
- IGHV1-12 | n.203G>A | RNA (SNP) | VAF 27/45 reads (60%) | catalogued as rs782563296; called by muse, mutect2, varscan2
- MAGED2 | c.1272-272G>A | Intron (SNP) | VAF 74/157 reads (47%) | catalogued as COSV99514752; called by muse, mutect2, varscan2
- MAZ | c.1280-500G>A | Intron (SNP) | VAF 14/17 reads (82%) | catalogued as COSV50714526; called by muse, mutect2
- NGF | c.-1A>C | 5'UTR (SNP) | VAF 37/106 reads (35%) | catalogued as COSV101049670; called by muse, mutect2, varscan2
- PTPN7 | c.-52-15G>A | Intron (SNP) | VAF 36/77 reads (47%) | catalogued as COSV100460115; called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6378G>A | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100218641; called by muse, mutect2, varscan2
- SERPINA13P | n.230C>T | RNA (SNP) | VAF 7/11 reads (64%) | catalogued as rs1390492991; called by muse, mutect2, varscan2
- SUN1 | c.659-1419C>T | Intron (SNP) | VAF 102/216 reads (47%) | catalogued as rs778740477, COSV100568794, COSV61777549; called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1157C>T | Intron (SNP) | VAF 24/52 reads (46%) | catalogued as COSV64750427; called by muse, varscan2
